Somatic mutation profile of tumor specimen TARGET-10-PASKCL-09B (aliquot TARGET-10-PASKCL-09B-01D) from TARGET case TARGET-10-PASKCL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,631 days).
Specimen TARGET-10-PASKCL-09B: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 792c4f91-5387-4628-858b-92c8804d3613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKCL-10A (Blood Derived Normal), aliquot TARGET-10-PASKCL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f90f3832-b4ec-4fa0-95ed-f9c2f21f7e96

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 3, Intron 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.1614G>A p.M538I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV62816178; called by muse, mutect2, varscan2
- ARSI | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV60817575; called by muse, mutect2, varscan2
- ATP10D | c.2660_2661insGTTACATT p.L889Hfs*21 | Frame Shift Ins (INS) | VAF 28/50 reads (56%) | catalogued as COSV56707964; called by mutect2, pindel*, varscan2*
- DNM2 | c.1091G>C p.R364P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV58957489, COSV58961647; called by muse, mutect2, varscan2
- PHC2 | c.2288G>A p.R763Q (on ENST00000257118 / NM_198040.2; = p.R228Q on NM_004427.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs752781137, COSV57104449; called by muse, mutect2, varscan2
- PHF6 | c.812A>G p.E271G (on ENST00000332070 / NM_032458.3; = p.E272G on NM_032335.3) | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59702598; called by muse, mutect2, varscan2
- PPP4C | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54222048, COSV54223359; called by muse, mutect2, varscan2
- SIDT2 | c.1661G>A p.G554D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280264947, COSV54057316; called by muse, mutect2, varscan2
- TMEM190 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1349084196, COSV52581512; called by muse, mutect2
- TSPYL2 | c.1471delinsCCC p.E491Pfs*134 | Frame Shift Ins (INS) | VAF 69/78 reads (88%) | catalogued as COSV64921301; called by pindel, varscan2*
- CYP2U1 | c.646dup p.D216Gfs*15 | Frame Shift Ins (INS) | VAF 39/102 reads (38%) | called by mutect2, pindel, varscan2
- PGR | c.48C>T p.G16= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs775718445; called by muse, varscan2
- SORCS2 | c.684C>T p.D228= | Silent (SNP) | VAF 51/97 reads (53%) | called by muse, mutect2, varscan2
- TLX3 | c.618G>A p.T206= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs984773220, COSV99740712; called by muse, mutect2, varscan2
- TPST2 | c.474G>A p.K158= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs1569181230; called by muse, mutect2, varscan2
- ACOT12 | c.*138del | 3'UTR (DEL) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- MAGEB3 | c.-20T>C | 5'UTR (SNP) | VAF 15/16 reads (94%) | called by mutect2, varscan2
- PHACTR1 | c.1728-11T>C | Intron (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- ZAP70 | c.890-29C>T | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
